Somatic mutation profile of tumor specimen 0DB2B9 from CCDI case PBBKLS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 16.6 years (6,049 days).
Specimen 0DB2B9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0348f07-6c74-4a72-9234-cbf5bbc69fbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB2AM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/193b66b1-9d02-4ffd-8b24-ca53350f478a

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 210/524 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2
- SLC10A2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 99/310 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs201821506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UST | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV66547976; called by muse, varscan2
- AP1B1 | c.2310-89C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- BEGAIN | c.15-82C>T | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, varscan2
